FM case AD14986 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Bladder.
https://portal.gdc.cancer.gov/cases/d4568fd4-e13e-4d2a-babb-df2abb5195de

Male, 81.8 years: Adenocarcinoma, NOS (ICD-O-3 8140/3) of the bladder; primary biopsied or resected from the bladder. Tumor nuclei on the sequenced sample's slide: 43% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
